Surgical pathology report (de-identified scan), TCGA case TCGA-EO-A22U, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University Health Network, specimen TCGA-EO-A22U-01A (Primary Tumor).

[page 1 of 3]
ICD-0-3

adenocarcinoma, endometrioid, nos 8380/3
Site: Endometrium C54.1 for 4/21/11

Surgical Pathology Consultation Report

Gender: F

Specimen(s) Received

1. Ovary: bilateral, bilateral fallopian tubes, uterus and cervix
2. Omentum: Omental biopsy

Diagnosis

1. Uterus, cervix, bilateral ovaries and fallopian tubes:

Uterus:

Endometrial adenocarcinoma, endometrioid type, FIGO grade 3/3 with:

- Maximum tumour dimension: 2.8 cm
- Invasion into the outer half of the myometrium
- Negative for involvement of cervix
- No evidence of lymphovascular space invasion
- Other: multiple intramural leiomyomata, adenomyosis

Right fallopian tube: paratubal cysts

Left fallopian tube: paratubal cysts

Bilateral ovaries: no diagnostic pathology

PLEASE SEE COMMENT and SYNOPSIS REPORT

2. Omentum, biopsy:

Fibroadipose tissue with no diagnostic pathology

One lymph node, negative for carcinoma (0/1)

Reviewed (initials)		

KMA *for 4/21/11*

Synoptic Data

----- MACROSCOPIC -----

Specimen Type:	Total Hysterectomy
Tumor Site:	Fundus
Tumor Size:	Greatest dimension: 2.8 cm
Other Organs Present:	Right ovary
	Left ovary
	Right fallopian tube

[page 2 of 3]
	Left fallopian tube
	Omentum
----- MICROSCOPIC -----	
Histologic Type:	Endometrioid adenocarcinoma, not otherwise characterized
Histologic Grade:	G3: More than 50% nonsquamous solid growth
Myometrial Invasion:	Invasion Present
	Depth of invasion: 10 mm, Myometrial thickness: 12 mm
Cervix Involvement:	None
LUS Involvement:	No
Venous/Lymphatic Invasion:	Absent
Nodal Involvement:	No nodes submitted
Margins:	Uninvolved by invasive carcinoma
	Distance of invasive carcinoma from closest margin: 2 mm
	uterine serosa
Primary Tumor (pT):	pT1c (IC): Tumor invades one-half or more of the myometrium
Regional Lymph Nodes (pN):	pNX: Regional lymph nodes cannot be assessed
	Number of regional lymph nodes examined: 0
	Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	pMX: Distant metastasis cannot be assessed
Additional Pathologic Findings:	Other: leiomyomata, adenomyosis
Neoadjuvant Treatment:	No
Collaborative Staging Extension:	Not applicable

Comment

Tumor demonstrated two architectural pattern with glandular and papillary structures merging with solid sheets. The solid component occupies more than 50% of total. Focal squamous differentiation is identified. Focally tumor cells show very high-grade nuclei and bizarre nuclear morphology.

Immunohistochemistry staining shows glandular areas show positive staining with ER but weak focal staining with p53 and negative staining with p16. The solid areas show negative staining with ER but patchy positive staining with p53 and patchy positive staining with p16. The overall morphological and immunohistochemistry features of this tumour is consistent with grade 3/3 endometrioid adenocarcinoma of endometrium.

Electronically

verified hv:

Clinical History

endometrial Ca

Gross Description

1. The specimen labeled the patient's name and as "Ovary: bilateral, bilateral fallopian tubes, uterus and cervix", consists of a 74.3 g, 6.8 SL x 4.0 ML x 2.3 cm AP hysterectomy, bilateral salpingo-oophorectomy specimen, received fresh. Vaginal cuff is not present. The exocervix measures 2.4 cm in maximum diameter. The external os is round and measures 0.3 cm in diameter. The endocervical canal measures 3.4 cm in length and shows a 0.6 cm polyp attached to the posterior endocervical wall. The uterine cavity measures 2.8 x 2.8 cm. There is a large infiltrative mass occupying the entire uterine cavity (anterior and posterior), measuring 2.8 ML x 2.2 SL x 1.0 cm in thickness. The mass is white-tan and friable and is noted grossly to be invading the outer half of the myometrium. The endometrium measures 1.0 cm in thickness. The myometrium has a maximum thickness of 1.3 cm and has small firm white nodules in it

[page 3 of 3]
measuring 0.4 cm in maximum dimensions. The serosa is smooth and glistening with a 0.9 cm nodule noted on the posterior fundus. The right fallopian tube measures 5.0 cm in length x 0.5 cm in diameter and includes fimbriated end, and shows small paratubal cysts (0.2 cm). The right ovary measures 2.1 x 0.9 x 0.4 cm and is grossly unremarkable. The left fallopian tube measures 5.5 cm in length x 0.5 cm in diameter and includes fimbriated end. The left ovary measures 1.9 x 1.1 x 0.5 cm and is grossly unremarkable. Sections of both fallopian tubes and ovaries and endometrial tumour are sampled for tissue banking. Representative sections are submitted as follows:

- 1A L ovary and fallopian tube, submitted for Biobank
- 1B R ovary and fallopian tube, submitted for Biobank
- 1C Endometrial tumour section, submitted for Biobank
- 1D-1E R fallopian tube, submitted in toto (fimbriae in 1E)
- 1F R ovary, submitted in toto
- 1G-1H L fallopian tube, submitted in toto (fimbriae in 1G)
- 1I L ovary, submitted in toto
- 1J-1K anterior cervix to lower uterine segment
- 1L-1M posterior cervix to lower uterine segment, polyp in 1M
- 1N-1P anterior endo-myometrium with tumour (longitudinal section in 1P)
- 1Q-1T posterior endo-myometrium with tumour

2. The specimen labeled the patient's name and as "Omentum, omental biopsy", consists of a 12.3 g, 8.0 x 4.0 x 1.2 cm piece of omentum with no grossly identifiable lesion. Representative sections are submitted in blocks 2A-2D.

Source: NCI Genomic Data Commons file ab65f4c8-0912-4020-a6a3-53cda76a9536 (TCGA-EO-A22U.DB7D72BC-F9C7-4726-98F4-A4F642B125C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).